CCDI case PBCCFK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined sites within respiratory system and intrathoracic organs.
https://portal.gdc.cancer.gov/cases/02dd8138-769b-43de-a8f2-138be9d73069

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pleuropulmonary blastoma: ICD-O-3 morphology code: 8973/3; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 0.1 years (33 days).

Biospecimens (3 samples)
- Sample 0DOG2X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOG3H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOG3Q: Tissue type: Tumor; Specimen type: Solid Tissue.
